Somatic mutation profile of tumor specimen TCGA-YL-A9WX-01A (aliquot TCGA-YL-A9WX-01A-21D-A41K-08) from TCGA case TCGA-YL-A9WX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-YL-A9WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e031387d-1b7d-40c9-bda0-b82ba88fcdc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WX-10A (Blood Derived Normal), aliquot TCGA-YL-A9WX-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d725c56d-fecd-400a-b0aa-5bd41709e747

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- CBLL1 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99755466; called by muse, mutect2
- CUL2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66081586; called by muse, mutect2
- C5 | c.4242A>G p.E1414= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV99797315; called by muse, mutect2, varscan2
- CDH4 | c.1380C>T p.V460= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs369825987; called by muse, mutect2, varscan2
- ENC1 | c.30G>A p.K10= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100187957; called by muse, mutect2, varscan2
- ITIH2 | c.2001G>A p.P667= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs568011933, COSV100623190; called by mutect2, varscan2
- PARD3 | c.2886T>A p.S962= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100400431; called by muse, mutect2
- PCDHA3 | c.1659G>A p.V553= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100793209; called by muse, mutect2, varscan2
- SF3A3 | c.772C>T p.L258= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100885697, COSV65955564; called by muse, mutect2
